Gene-level copy-number profile of tumor specimen C3L-01328-01 from CPTAC case C3L-01328, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 71.9 years (26,268 days).
Specimen C3L-01328-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dc271b15-f5e9-4450-8e15-5963e3ba39bb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01328-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/11633470-0ed9-4d49-a2f3-555f4d2fc0be

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,619; copy number 2: 46,331; copy number 3: 5,345; copy number 4: 442; copy number 5: 36; copy number 6: 59; copy number 7: 71; copy number 9: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 170 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:2,695,765–5,521,536, 74 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:18,087,892–19,143,689, 71 genes, copy number 7 (broad region; genes not listed).
- chr19:37,312,837–37,369,365, 1 gene, copy number 9 (within-gene range 3–9): ZNF875.
- chr19:37,337,236–37,906,677, 24 genes, copy number 6–9: AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87.

Autosomal genes at a single copy (total copy number 1): 3,763. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
